Surgical pathology report (de-identified scan), TCGA case TCGA-23-1122, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1122-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATH

PATIENT:

Hospital No.:

Date of Birth:

Soc. Sec. No.:

Location:

Pathologist:

Assistant:

Attending MD:

Ordering MD:

Copies To:

DIAGNOSIS:

- 1: UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:
- Cervix:
- Chronic endocervicitis
- Nabothian cysts
- Negative for malignancy
- Endometrium:
- Non-phasic atrophic endometrium
- Endometrial polyp with complex hyperplasia and focal high grade and anaplastic mullerian-derived adenocarcinoma (see Comment)
- Focal metastatic nodules on the posterior serosal aspect
- Myometrium:
- Adenomyosis
- Leiomyoma
- 2: OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY:
- High grade mullerian-derived adenocarcinoma involving the ovary and fallopian tube
- 3: OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY:
- High grade mullerian-derived adenocarcinoma, (see Microscopic Description and Comment) involving the ovary and fallopian tube
- 4: OMENTUM, NUMBER 1, PARTIAL OMENTECTOMY:
- Metastatic mullerian-derived adenocarcinoma
- 5: LYMPH NODE, PELVIC, LEFT, EXCISION:
- Five (5) lymph nodes with reactive follicular hyperplasia, sinus histiocytosis and focal calcifications
- Negative for malignancy
- 6: LYMPH NODE, RIGHT EXTERNAL ILIAC, EXCISION:
- One (1) lymph node with reactive follicular hyperplasia
- Negative for malignancy
- 7: OMENTUM, NUMBER 2, PARTIAL OMENTECTOMY:
- Metastatic mullerian-derived adenocarcinoma

HISTORY:

MICROSCOPIC:

The tumor shows features of a high grade mullerian-derived adenocarcinoma, papillary serous type. The possibilities that this

[page 2 of 3]
represents primary uterine papillary serous adenocarcinoma with metastases, or multifocal papillary serous adenocarcinoma with involvement of the bilateral ovaries, endometrium, and right fallopian tube should be considered. The latter scenario is favored. Selected slides were reviewed by [REDACTED] concurs with the interpretation.

GROSS:

1: UTERUS

Labeled "uterus" and received in formalin is a 410 gram enlarged uterus without attached bilateral adnexa. The uterus is 9.0 cm fundus to cervix, 6.0 cm cornu to cornu, and 4.5 cm anterior to posterior. The serosa is diffusely congested with numerous dark red fibrous adhesions. The cervix is 3.5 x 3.0 cm with a small attached vaginal cuff ranging from 0.5 cm posteriorly to 1.0 cm anteriorly. The mucosa is smooth focally hyperemic and surrounds a patent 0.1 cm os. The squamo-columnar junction is ill-defined. The endocervical canal is 2.5 cm in length, tan and rugose with numerous nabothian cysts measuring up to 0.6 cm in greatest dimension. The endometrial cavity is 4.0 cm superior to inferior, and 3.0 cm laterally. The endometrium is tan, smooth up to 0.1 cm in thickness with two, pink-tan friable polypoid lesions on the left lateral aspect of both the anterior and posterior walls which are 0.5 and 1.0 cm in greatest dimensions respectively. There is also a firm 1.0 x 0.5 cm sessile polypoid lesion on the fundus. The coarsely trabecular pink-tan myometrium is up to 1.7 cm in thickness. There is a single 1.3 cm in diameter subserosal leiomyoma which has a typical grey-white whorled appearance. Representative sections are submitted.

- A. Anterior cervix - 1
- B. Posterior cervix - 1
- C. Anterior uterine corpus, full thickness including serosal adhesions - 1
- D. Posterior uterine corpus, including serosal adhesions - 1
- E. Anterior uterine fundus with polypoid lesion - 1
- F. Posterior uterine fundus with polypoid lesion - 1
- G. Fundic endometrium nodule - 1
- H. Fundic subserosal nodule and adhesions - 3

2: LEFT TUBE AND OVARY

Labeled "left tube and ovary", received fresh in the Operating Room and subsequently fixed in formalin is an enlarged 8.5 cm long fimbriated fallopian tube with a maximum diameter of 3.0 cm. The serosa is red-tan with numerous fibrous adhesions. Upon sectioning, the lumen is filled with tan, friable lobulated tumor. The fimbriated end is tan-red and is also involved by tumor. There is an underlying 5.5 x 3.5 x 3.0 cm disrupted friable tumor mass which has numerous fibrous adhesions. Upon sectioning in this region, the mass is predominantly solid, homogeneous and lobulated with a few cystic spaces measuring up to 1.7 cm in greatest dimension. The cysts are thin and smooth and predominantly thin walled with a 0.6 cm excrescence and contain a small amount of bloody fluid. There is no grossly identifiable residual ovarian parenchyma remaining. Representative sections are submitted.

- I, J. Fallopian tube with tumor - 1 each
- K. Underlying mass with cystic spaces - 2
- L. 1

3: RIGHT OVARY

Labeled "right ovary" and received in formalin is a 480 gram, 13.0 x 10.5 x 8.0 cm fluctuant bosselated ovary. The external surface is covered by numerous red-tan tumor implants and fibrous adhesions as well as a 6.5 x 1.0 cm convoluted fimbriated fallopian tube. The external surface of the fallopian tube also is covered by tan-red tumor. There is an adjacent 2.0 cm smooth thin walled paratubal cyst. Upon sectioning, the fallopian tube has a stellate patent lumen.

[page 3 of 3]
The cut surface consists of approximately 70% solid tan lobulated tumor with multifocal areas of hemorrhage and necrosis and 30% is cystic. The cysts are filled with a red tinged serous fluid. There is also a small amount of gelatinous matrix in both the solid and cystic components. Representative sections are submitted.

M. Fallopian tube with paratubal cyst and tumor - 2
N,O. Solid and cystic component - 2 each
P,Q. Solid and cystic component in relation with external tumor
nodules - 2 each

4: OMENTUM NO.1

Labeled "omentum no.1" and received in formalin is a 3.5 x 3.5 x 1.0 cm aggregate of tan-yellow lobulated fat. Upon sectioning, the cut surfaces are tan-yellow lobulated and fatty with a single 0.4 cm segment of firm tan-grey tumor. Representative sections are submitted.

R. Multiple

5: LEFT PELVIC LYMPH NODE

Labeled "left pelvic lymph node" and received in formalin is a 3.0 x 2.0 x 0.5 cm aggregate of tan-yellow lobulated fat containing four, firm, tan-red lymph nodes ranging from 1.0 to 1.5 cm in greatest dimension. The lymph nodes are entirely submitted.

\$ 5

6: RIGHT EXTERNAL ILIAC NODE

Labeled "right external iliac node" and received in formalin is a 2.0 x 1.7 x 1.0 cm aggregate of tan-yellow lobulated fat containing a single 1.5 x 0.7 x 0.6 cm congested lymph node.
All embedded.

T. 1

7: OMENTUM NO.2

Labeled "omentum no. 2" and received in formalin is a 15.0 x 12.0 x 2.0 cm aggregate of multiple fragments of omentum. Upon sectioning, the cut surface is tan-yellow, lobulated and fatty with five, firm, tan tumor nodules ranging from 0.5 to 2.0 cm in greatest dimension which involve approximately 10% of the cut surface. Representative sections are submitted.

U. 4

Gross dictated by

OPERATIVE CONSULT (GROSS):
Bilateral ovarian, left ovarian tumor
Mullerian-derived

Guerrilla Warfare

Source: NCI Genomic Data Commons file 378880bd-a5e7-4c2a-9ec9-fe226f5cf4f8 (TCGA-23-1122.9507D553-B1C7-4B71-90C1-064FD8EF15BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).